Gene-level copy-number profile of tumor specimen TCGA-2G-AAGA-01A from TCGA case TCGA-2G-AAGA, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 38.5 years (14,053 days).
Specimen TCGA-2G-AAGA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.8c7d31fe-ecad-46c2-b8c9-05e8bea0e13a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAGA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4febcff-6d8a-414e-b7e0-c7c23701746b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 13,609; copy number 3: 27,604; copy number 4: 13,883; copy number 5: 3,865; copy number 7: 9; copy number 9: 850.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAGA-01A-11D-A42X-01): tumor purity 0.64, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 859 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:81,946,444–82,443,777, 1 gene, copy number 7 (within-gene range 5–7): CACNA2D1.
- chr7:82,589,848–83,649,139, 8 genes, copy number 7 (within-gene range 5–7): MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1.
- chr12:66,767–34,249,958, 850 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
